Somatic mutation profile of tumor specimen TCGA-SH-A7BH-01A (aliquot TCGA-SH-A7BH-01A-11D-A34C-32) from TCGA case TCGA-SH-A7BH, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 65.3 years (23,850 days).
Specimen TCGA-SH-A7BH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fdc5fc1-92c8-4761-aec5-8e771433b1c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SH-A7BH-10A (Blood Derived Normal), aliquot TCGA-SH-A7BH-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06bc72ed-a5bb-4ed8-b3f5-7ada39e49537

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 34/47 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRE1 | c.581A>T p.N194I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV51671890; called by muse, mutect2, varscan2
- AHCYL2 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs192789526; called by muse, mutect2, varscan2
- ANKRD30A | c.1291G>A p.V431M (on ENST00000611781; = p.V375M on NM_052997.2) | Missense Mutation (SNP) | VAF 78/89 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs373496322, COSV64609083; called by muse, mutect2, varscan2
- ARAP2 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1195969006; called by muse, mutect2, varscan2
- CFAP157 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs765229107, COSV58851930; called by muse, mutect2, varscan2
- COBL | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771778534, COSV54358837; called by muse, mutect2, varscan2
- DENND4B | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV99055938; called by muse, mutect2, varscan2
- FCGRT | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs1485223386; called by muse, mutect2, varscan2
- IRAK4 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1565665934; called by muse, mutect2, varscan2
- ITGB1BP2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.662); catalogued as rs376350791, COSV52136110; called by muse, mutect2, varscan2
- KCNQ4 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.48); PolyPhen benign (0.122); catalogued as rs1200500779, COSV61271954; called by muse, mutect2, varscan2
- LIM2 | c.421A>G p.I141V (on ENST00000596399 / NM_001161748.2; = p.I183V on NM_030657.4) | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.605); catalogued as rs764435572; called by muse, mutect2, varscan2
- MID2 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs190213818; called by muse, mutect2, varscan2
- NOX1 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373860304, COSV54197239; called by muse, mutect2, varscan2
- OTUD7B | c.1630G>A p.G544S | Missense Mutation (SNP) | VAF 120/280 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs782204756, COSV64915963; called by muse, mutect2, varscan2
- PDIA4 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as rs763122880; called by muse, mutect2, varscan2
- PINK1 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146126901, CM138337; called by muse, mutect2, varscan2
- PPP1R13B | c.2624C>T p.S875L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1252412178, COSV52455650; called by muse, mutect2, varscan2
- RGL2 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758623435, COSV65842633; called by muse, mutect2, varscan2
- SUGCT | c.1145C>A p.S382Y (on ENST00000335693 / NM_001193313.2; = p.S408Y on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV59319670; called by muse, mutect2, varscan2
- BRIP1 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 47/57 reads (82%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CHI3L1 | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COL24A1 | c.607T>G p.F203V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DECR2 | c.202-1G>A p.X68_splice | Splice Site (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- FYB1 | c.77C>G p.P26R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GPRC5D | c.144G>A p.M48I | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGLV1-50 | c.124A>C p.T42P | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- MIEF2 | c.581T>G p.V194G | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- MYLK4 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRD | c.2759G>A p.G920E | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- RBM47 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 69/88 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SLC17A5 | c.349T>A p.Y117N | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VRTN | c.2086G>A p.G696S | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ADAMTS14 | c.2559C>A p.L853= | Silent (SNP) | VAF 22/28 reads (79%) | called by muse, mutect2, varscan2
- DOT1L | c.1413C>T p.S471= | Silent (SNP) | VAF 79/183 reads (43%) | catalogued as COSV101288593; called by muse, mutect2, varscan2
- GRM5 | c.2307C>T p.N769= | Silent (SNP) | VAF 46/176 reads (26%) | catalogued as rs756305519, COSV59592302; called by muse, mutect2, varscan2
- GSDMA | c.528C>A p.S176= | Silent (SNP) | VAF 23/27 reads (85%) | called by mutect2, varscan2
- INPP1 | c.1137G>A p.K379= | Silent (SNP) | VAF 14/16 reads (88%) | called by muse, varscan2
- PABPC4 | c.1119G>A p.E373= | Silent (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- PCDHA6 | c.51G>A p.P17= | Silent (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- RUNX1 | c.918G>A p.P306= (on ENST00000344691 / NM_001001890.3; = p.P333= on NM_001754.5) | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as COSV55877461; called by muse, mutect2, varscan2
- SYMPK | c.705C>T p.A235= | Silent (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2
- TBXAS1 | c.1323C>T p.D441= | Silent (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- UNC79 | c.4515G>A p.G1505= (on ENST00000393151 / NM_001346218.2; = p.G1328= on NM_020818.5) | Silent (SNP) | VAF 93/113 reads (82%) | catalogued as rs368242839, COSV56396601; called by muse, mutect2, varscan2
- HTR3E | c.68-103T>G | Intron (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
